Gene-level copy-number profile of tumor specimen TCGA-AY-A8YK-01A from TCGA case TCGA-AY-A8YK, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IVA; Age at diagnosis: 44.2 years (16,140 days).
Specimen TCGA-AY-A8YK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.227b8084-5c0d-4b3e-8ced-38e6e74aae49.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AY-A8YK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3354f67b-e89f-493b-8970-119c902ccff6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 131; copy number 2: 6,938; copy number 3: 24,494; copy number 4: 16,800; copy number 5: 6,476; copy number 6: 1,118; copy number 7: 1,732; copy number 8: 1,215; copy number 9: 898; copy number 16: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AY-A8YK-01A-11D-A40O-01): tumor purity 0.57, ploidy 3.58, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,857 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–38,318,861, 679 genes, copy number 7–16 (within-gene range 6–16) (broad region; genes not listed).
- chr7:142,328,297–142,802,748, 79 genes, copy number 7 (broad region; genes not listed).
- chr8:58,805,412–59,119,147, 1 gene, copy number 7 (within-gene range 4–7): TOX.
- chr8:58,991,720–82,961,926, 358 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr8:94,708,952–113,616,958, 295 genes, copy number 7 (broad region; genes not listed).
- chr8:115,408,496–128,187,101, 183 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr13:18,467,172–19,783,019, 53 genes, copy number 7: ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4, LINC00387, TERF1P5, FAM207BP, GXYLT1P1, CNN2P12, ZNF965P, CYP4F34P, SNX18P26, LINC00328-2P, ANKRD20A9P, RHOT1P3, RNU6-55P, RNU6-76P, SNX19P2, LINC00408, AL355516.1, PHF2P2, LINC00442, USP24P1, GTF2IP3, AL137001.1, AL137001.2, RNA5SP24, CENPIP1, AL139327.2, SMPD4P2, AL139327.3, TUBA3C, AL139327.1, PSPC1P1, ANKRD26P3, MRPL3P1, LINC00421, PARP4P2, CCNQP3, AL356259.1, SLC25A15P2, TPTE2, CYCSP32, MRPS31P2, ESRRAP1, LINC00350, CASC4P1, MPHOSPH8, PSPC1-AS2, PSPC1, RN7SL166P.
- chr13:24,924,677–24,968,487, 1 gene, copy number 8 (within-gene range 4–8): TPTE2P1.
- chr13:24,943,575–114,337,626, 1,214 genes, copy number 8 (broad region; genes not listed).
- chr14:22,096,032–22,513,998, 68 genes, copy number 7 (broad region; genes not listed).
- chr17:27,082,690–27,754,954, 28 genes, copy number 7: TUFMP1, AC129926.2, AC129926.1, RPL34P31, RPS16P8, AC026254.1, MIR4522, WSB1, AC026254.2, SYPL1P2, AC090615.1, TBC1D3P5, KSR1, AC069366.2, AC069366.1, ITM2BP1, AC015688.4, AC015688.6, LGALS9, NOS2P1, AC015688.3, AC015688.5, CPDP1, AC015688.2, AC015688.1, AC130289.1, AC130289.2, LGALS9DP.
- chr20:30,278,906–64,313,132, 898 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 131. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
